Somatic mutation profile of tumor specimen TCGA-77-8131-01A (aliquot TCGA-77-8131-01A-11D-2244-08) from TCGA case TCGA-77-8131, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.9 years (26,611 days).
Specimen TCGA-77-8131-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20231622-112e-4dc5-969d-8f634f82b25a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8131-10A (Blood Derived Normal), aliquot TCGA-77-8131-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32ff9817-291b-448b-a4b4-fffe88f7e74f

The open-access MAF lists 73 somatic variants for this specimen: 47 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 25, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL1 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99860387; called by muse, mutect2
- ADGRV1 | c.3739G>C p.E1247Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs1396785235, COSV101315544; called by muse, mutect2
- AHCYL1 | c.876C>G p.C292W | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100779455; called by muse, mutect2
- CAMK2D | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV99593342; called by muse, mutect2, varscan2
- CCDC121 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99269894; called by muse, mutect2, varscan2
- CDH9 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV50380580, COSV99142013; called by muse, mutect2, varscan2
- CLRN3 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs138300341, COSV64098340; called by muse, mutect2
- ELF1 | c.614-2A>G p.X205_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99522867; called by muse, mutect2
- ENAH | c.1589A>T p.D530V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV99490168; called by muse, varscan2
- F13A1 | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.221); catalogued as COSV53554122, COSV53559555; called by muse, mutect2
- FBXO11 | c.1042T>A p.F348I (on ENST00000403359 / NM_001190274.2; = p.F264I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as COSV100319098; called by muse, varscan2
- HCK | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1344765069, COSV99393783; called by muse, mutect2, varscan2
- HEATR6 | c.1211C>G p.A404G | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV99482139; called by muse, mutect2, varscan2
- HELZ2 | c.4541G>C p.G1514A (on ENST00000467148 / NM_001037335.2; = p.G945A on NM_033405.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV101427527; called by muse, mutect2
- HUWE1 | c.2614C>G p.R872G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs782695696, COSV99470838; called by muse, mutect2
- IFNA5 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs765147470, COSV99423637; called by muse, mutect2, varscan2
- ILDR1 | c.417C>A p.D139E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99878003; called by muse, mutect2, varscan2
- LDLRAD4 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100761996, COSV63335286; called by muse, mutect2
- LTF | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV99206974; called by muse, mutect2, varscan2
- MYOT | c.1367T>A p.V456D | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99296042; called by muse, mutect2, varscan2
- NBAS | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.1); catalogued as COSV99867632; called by muse, mutect2
- NECTIN4 | c.1503C>G p.I501M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100919837; called by muse, mutect2, varscan2
- NFXL1 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV100216622; called by mutect2, varscan2
- NUP98 | c.2842A>T p.S948C (on ENST00000359171 / NM_001365126.1; = p.S931C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100261612; called by muse, mutect2, varscan2
- OR6V1 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101389220; called by muse, mutect2, varscan2
- PLXNA1 | c.3707A>G p.Y1236C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); catalogued as COSV99302418; called by muse, mutect2
- PYGL | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99368307; called by muse, mutect2, varscan2
- RETSAT | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99805904; called by muse, mutect2
- RNF145 | c.983C>T p.T328I (on ENST00000424310 / NM_001199383.2; = p.T356I on NM_144726.2) | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1276725271, COSV99193268; called by muse, mutect2, varscan2
- SERPINA5 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431711373, COSV100291499; called by muse, mutect2
- SGK1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100775144; called by muse, mutect2, varscan2
- SLC6A13 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.077); catalogued as COSV100569782; called by muse, mutect2, varscan2
- SLC6A3 | c.891C>G p.Y297* | Nonsense Mutation (SNP) | VAF 15/121 reads (12%) | catalogued as COSV99547904; called by muse, mutect2, varscan2
- SMC5 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.771); catalogued as COSV100746982; called by muse, mutect2, varscan2
- TDRD1 | c.2411A>G p.E804G | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99314157; called by muse, mutect2
- TNF | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.267); catalogued as COSV101403145; called by muse, mutect2, varscan2
- TNFAIP3 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV52798758; called by muse, varscan2
- UBR4 | c.10795G>T p.V3599L | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100920325; called by muse, mutect2
- USF3 | c.3043A>G p.K1015E | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100324802; called by mutect2, varscan2
- VRTN | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs1191327811, COSV56442808; called by muse, mutect2, varscan2
- WNK4 | c.1170+1G>A p.X390_splice | Splice Site (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99519333; called by muse, mutect2, varscan2
- YTHDC2 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.173); catalogued as COSV99362960; called by muse, mutect2
- IMPG2 | c.180_190del p.K61Afs*8 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- KIR3DL3 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2
- SPRY2 | c.17dup p.S7Efs*14 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- TOPORS | c.2618_2636del p.G873Vfs*29 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel
- ANKRD27 | c.2424C>G p.L808= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100042584; called by muse, mutect2, varscan2
- ANKRD44 | c.1452T>C p.D484= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as COSV99984260; called by muse, mutect2, varscan2
- CALM2 | c.273T>A p.R91= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99700652; called by muse, mutect2, varscan2
- CHD9 | c.816A>G p.S272= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV101271931; called by mutect2, varscan2
- EDRF1 | c.1032A>T p.P344= (on ENST00000356792 / NM_001202438.2; = p.P310= on NM_015608.2) | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV61765939; called by muse, mutect2
- GLUD1 | c.1284C>G p.L428= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV99517949; called by muse, mutect2, varscan2
- GRIN2A | c.867G>A p.E289= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100408551; called by muse, mutect2, varscan2
- GSX1 | c.648C>G p.G216= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV57232762; called by muse, mutect2
- KIR3DL3 | c.381G>T p.L127= | Silent (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- MAP2 | c.2970C>T p.F990= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs780188011, COSV52291286; called by muse, mutect2, varscan2
- MED17 | c.1599G>A p.Q533= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV99315761; called by muse, mutect2, varscan2
- MRPL10 | c.364C>T p.L122= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99270346; called by muse, mutect2, varscan2
- NSUN6 | c.666A>G p.P222= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101045386; called by muse, mutect2, varscan2
- OR5H2 | c.126C>A p.I42= | Silent (SNP) | VAF 44/492 reads (9%) | catalogued as COSV100788659; called by muse, mutect2
- PSD4 | c.2502G>A p.Q834= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV99830871; called by muse, mutect2
- RASAL2 | c.2172T>G p.S724= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100862444; called by muse, mutect2
- SIAH2 | c.228G>A p.S76= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100469511; called by muse, mutect2
- SLC1A5 | c.1002C>T p.Y334= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV69467727; called by muse, mutect2
- SLC30A3 | c.765C>G p.L255= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as COSV99273479; called by muse, mutect2
- SPHKAP | c.1464C>A p.S488= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100763763, COSV60893171; called by muse, mutect2
- TIAM1 | c.2175A>G p.K725= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs745308249, COSV99733167; called by muse, mutect2, varscan2
- TRIM26 | c.186G>A p.K62= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV101359429; called by muse, mutect2, varscan2
- TXNDC2 | c.1374C>T p.D458= (on ENST00000306084 / NM_001098529.2; = p.D391= on NM_032243.6) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100045790; called by muse, mutect2, varscan2
- XRCC6 | c.864C>G p.L288= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as rs1263826667, COSV100777787, COSV100777820; called by muse, mutect2, varscan2
- ZNF592 | c.3291A>G p.R1097= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV100245709; called by muse, varscan2
- FAM160A2 | c.1435+35C>T | Intron (SNP) | VAF 21/163 reads (13%) | catalogued as COSV99791770; called by muse, mutect2, varscan2
